Somatic mutation profile of tumor specimen TCGA-GU-AATO-01A (aliquot TCGA-GU-AATO-01A-11D-A391-08) from TCGA case TCGA-GU-AATO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,684 days).
Specimen TCGA-GU-AATO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5baddc39-d871-4de2-aed9-8cafb7b3f5b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-AATO-10A (Blood Derived Normal), aliquot TCGA-GU-AATO-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54901314-a1ec-42a7-ae4e-9a575954be29

The open-access MAF lists 355 somatic variants for this specimen: 260 protein-altering or splice-affecting, 87 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 87, Nonsense Mutation 19, Splice Site 5, Intron 4, Nonstop Mutation 3, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs876659539, CD130087, CM010753, COSV57331263, COSV57378987; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD18 | c.978C>G p.H326Q (on ENST00000398965 / NM_001039717.2; = p.H233Q on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV66293467; called by muse, mutect2
- ACTN4 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752441330, COSV53144617; called by muse, mutect2, varscan2
- ADAM7 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV51537395; called by muse, mutect2, varscan2
- ADAMTS3 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV54388265; called by muse, mutect2, varscan2
- ADGRG4 | c.7255G>T p.D2419Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV54952570; called by muse, mutect2, varscan2
- AHCTF1 | c.3610G>C p.E1204Q (on ENST00000366508; = p.E1178Q on NM_015446.5) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV58247893; called by muse, mutect2, varscan2
- AHDC1 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as COSV99899786, COSV99899841; called by muse, mutect2
- AHNAK | c.10717A>C p.K3573Q | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57208672; called by muse, mutect2, varscan2
- AKAP9 | c.10499G>C p.R3500T (on ENST00000359028; = p.R3476T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV62342275, COSV62352310; called by muse, mutect2, varscan2
- AKNA | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232269629, COSV56311959; called by muse, mutect2, varscan2
- AKR1A1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs753056697, COSV61086573; called by muse, mutect2, varscan2
- AL592490.1 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV69425415; called by muse, mutect2
- ALDH9A1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV61339473; called by muse, mutect2, varscan2
- AMACR | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV99673321; called by muse, mutect2, varscan2
- AMPD1 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV62415536; called by muse, mutect2, varscan2
- ANKEF1 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65692151; called by muse, mutect2, varscan2
- ANKRD30A | c.2051C>G p.S684C (on ENST00000611781; = p.S628C on NM_052997.2) | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV64607318, COSV64611712; called by muse, mutect2, varscan2
- ANKRD40 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV53333065; called by muse, mutect2, varscan2
- APOLD1 | c.564G>T p.R188S (on ENST00000326765 / NM_001130415.2; = p.R157S on NM_030817.3) | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV58732366; called by muse, mutect2, varscan2
- AQP10 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as rs1451205256, COSV100270562, COSV59248736; called by muse, mutect2, varscan2
- ARHGAP31 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV51790944; called by muse, mutect2, varscan2
- ARID1B | c.5999G>T p.W2000L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as CM1310773, COSV51656309; called by muse, mutect2, varscan2
- ARID1B | c.6417G>C p.Q2139H | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51656323; called by muse, mutect2, varscan2
- ARID1B | c.6418A>T p.K2140* | Nonsense Mutation (SNP) | VAF 100/197 reads (51%) | catalogued as rs1554238096, COSV99273137; called by muse, mutect2, varscan2
- ASPRV1 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV57227697; called by muse, mutect2, varscan2
- ATP12A | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54514250, COSV99517411; called by muse, mutect2, varscan2
- ATP8B2 | c.1384G>A p.E462K (on ENST00000672630; = p.E429K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV59245406; called by muse, mutect2, varscan2
- AXL | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV56565886; called by muse, mutect2, varscan2
- B4GALNT2 | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 30/141 reads (21%) | catalogued as COSV55925428, COSV55926428; called by muse, mutect2, varscan2
- BAZ2B | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100601139; called by muse, mutect2, varscan2
- BBX | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57881642; called by muse, mutect2, varscan2
- BMS1 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV65733439; called by muse, mutect2, varscan2
- BRWD1 | c.2181G>C p.Q727H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV60894167; called by muse, mutect2, varscan2
- C14orf39 | c.1763G>C p.*588Sext*4 | Nonstop Mutation (SNP) | VAF 93/140 reads (66%) | catalogued as COSV100408187; called by muse, mutect2, varscan2
- C1orf116 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV63943882; called by muse, mutect2, varscan2
- CADM1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59006497; called by muse, mutect2, varscan2
- CASP7 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV61881418; called by muse, mutect2, varscan2
- CASP9 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs2020897; called by muse, mutect2, varscan2
- CAT | c.1393G>C p.G465R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs764937602, COSV53810751, COSV53813271; called by muse, mutect2, varscan2
- CDC14A | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.564); catalogued as COSV60556592; called by muse, mutect2, varscan2
- CDKN2AIP | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56626679, COSV56626969; called by muse, mutect2, varscan2
- CEACAM6 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as COSV52267025, COSV52268874, COSV52268928; called by muse, mutect2, varscan2
- CEACAM8 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54990442; called by muse, mutect2, varscan2
- CEP250 | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV61169023; called by muse, mutect2, varscan2
- CHD8 | c.2606C>T p.S869F (on ENST00000646647 / NM_001170629.2; = p.S590F on NM_020920.4) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67870060; called by muse, mutect2, varscan2
- CHMP2A | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53396649; called by muse, mutect2, varscan2
- CLBA1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.152); catalogued as rs779420799, COSV101121095, COSV66347920; called by muse, mutect2, varscan2
- CLCN1 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58368642, COSV58369230; called by muse, mutect2, varscan2
- CLEC6A | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 28/213 reads (13%) | catalogued as COSV101165729; called by muse, mutect2, varscan2
- CLPTM1 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1359506612, COSV61611525; called by muse, mutect2, varscan2
- COL15A1 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV66641882, COSV66642858; called by muse, mutect2, varscan2
- COL1A1 | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as CM094108, COSV99868343; called by muse, mutect2, varscan2
- COLGALT1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV53108205; called by muse, mutect2, varscan2
- COPA | c.942G>C p.M314I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV54100370; called by muse, mutect2
- COQ3 | c.1109G>T p.*370Lext*26 | Nonstop Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as COSV99633105; called by muse, mutect2, varscan2
- CPED1 | c.2754G>C p.L918F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV59998165; called by muse, mutect2, varscan2
- CRNKL1 | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV55623951; called by muse, mutect2, varscan2
- CRTAM | c.1058A>G p.H353R | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57067124; called by muse, mutect2, varscan2
- CXCL10 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV60660855; called by muse, mutect2, varscan2
- DARS2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV53406304; called by muse, mutect2, varscan2
- DCAF8L1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV71595195; called by muse, mutect2, varscan2
- DCLK3 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101374125, COSV69362807; called by muse, mutect2, varscan2
- DDX42 | c.613C>G p.H205D | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63789734; called by muse, mutect2
- DEFB129 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.665); catalogued as rs1298551453, COSV55731182; called by muse, mutect2, varscan2
- DGCR8 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1385585441, COSV61226121; called by muse, mutect2, varscan2
- DHX8 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs1433701446, COSV52251094, COSV52251961; called by muse, mutect2, varscan2
- DLC1 | c.1840G>A p.A614T (on ENST00000276297 / NM_001348081.2; = p.A177T on NM_006094.5) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1306577883, COSV52296774; called by muse, mutect2, varscan2
- DNAH17 | c.4724G>C p.R1575T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67751628, COSV67761955; called by muse, mutect2, varscan2
- DNAJB14 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV62033223; called by muse, mutect2
- DNAJC13 | c.5986C>G p.L1996V | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV53448031; called by muse, mutect2, varscan2
- DOCK4 | c.5815C>T p.R1939* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs527410636, COSV101447983; called by muse, mutect2, varscan2
- DOCK5 | c.4944G>C p.E1648D | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV52398449; called by muse, mutect2, varscan2
- DSCC1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100558443; called by muse, mutect2, varscan2
- DYNC1H1 | c.11377G>A p.E3793K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64135487; called by muse, mutect2, varscan2
- ECM2 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV60739820; called by muse, mutect2, varscan2
- EEF1A1 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100303480; called by muse, mutect2, varscan2
- EFNB3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1411191870, COSV56833126; called by muse, mutect2, varscan2
- EGR1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1305588383, COSV53518511; called by muse, mutect2, varscan2
- EPHA6 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as COSV67565884, COSV67571155; called by muse, mutect2, varscan2
- EPS8L3 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100719770; called by muse, mutect2, varscan2
- ERF | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.499); catalogued as rs777136618, COSV99724879; called by muse, mutect2
- EXOSC9 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54665516; called by muse, mutect2, varscan2
- FLI1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858199; called by muse, mutect2
- FOXP4 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57218986; called by muse, mutect2, varscan2
- FREM2 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.55); catalogued as COSV54833124; called by muse, mutect2, varscan2
- FUT5 | c.1124G>C p.*375Sext*20 | Nonstop Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99398901, COSV99398989; called by muse, mutect2, varscan2
- GCSAM | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV58262944; called by muse, mutect2, varscan2
- GOLIM4 | c.1311G>C p.Q437H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58328894; called by muse, mutect2, varscan2
- GPALPP1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100689135, COSV62705580, COSV62706659; called by muse, mutect2, varscan2
- GPATCH1 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV50112622; called by muse, mutect2, varscan2
- GPR22 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.184); catalogued as rs749244821, COSV51746531; called by muse, mutect2, varscan2
- GRK1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs368488746; called by muse, mutect2
- H4-16 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); catalogued as COSV63761949; called by muse, mutect2
- HEATR1 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV63980268; called by muse, mutect2, varscan2
- HEATR6 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.261); catalogued as COSV51744599; called by muse, mutect2, varscan2
- HELZ | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62377303; called by muse, mutect2, varscan2
- HMCN1 | c.6932C>G p.S2311C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54888481, COSV54926508; called by muse, varscan2
- HNF4A | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754907741, COSV57381142, COSV57382049; called by muse, mutect2, varscan2
- HOXB2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57486283; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52374498; called by mutect2, varscan2
- HSD17B8 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV63002414; called by muse, mutect2, varscan2
- HSPA2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55969108; called by muse, mutect2, varscan2
- IFIT5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65655368; called by muse, mutect2, varscan2
- IL10 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65594413; called by muse, mutect2, varscan2
- IRS4 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV64533160; called by muse, mutect2, varscan2
- IRX4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1367996650, COSV51471639; called by muse, mutect2, varscan2
- ITGA1 | c.2633G>T p.C878F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs199770577, COSV50878782; called by muse, mutect2, varscan2
- ITPR2 | c.4180G>A p.E1394K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1348407190, COSV67267056; called by muse, mutect2, varscan2
- KAZN | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63207511; called by muse, mutect2, varscan2
- KCNMB1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs751855710, COSV51131482; called by muse, mutect2, varscan2
- KHNYN | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV52159577; called by muse, mutect2
- KIAA1217 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs143221112, COSV56814743; called by muse, mutect2, varscan2
- KIAA1522 | c.2339C>T p.P780L (on ENST00000373480 / NM_001198972.2; = p.P839L on NM_020888.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99615288; called by muse, mutect2
- KIF2A | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV66945102; called by muse, mutect2, varscan2
- KIF6 | c.1941G>C p.K647N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54672156; called by muse, mutect2, varscan2
- KMT2A | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1320199384, COSV63284022; called by muse, mutect2, varscan2
- KMT2C | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV51423429; called by muse, mutect2, varscan2
- KMT2D | c.3194C>T p.S1065L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99986550; called by muse, mutect2
- LRP1B | c.12493C>T p.H4165Y | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV67201125, COSV67210387, COSV67261032; called by muse, mutect2, varscan2
- LY86 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV57911470; called by muse, varscan2
- MAP3K3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51991743; called by muse, mutect2
- MAPK3 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755904687, COSV53772225; called by muse, mutect2, varscan2
- MBTD1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 182/255 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.645); catalogued as COSV64503104; called by muse, mutect2, varscan2
- MDP1 | c.435G>C p.M145I | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV51659927, COSV99164575; called by muse, mutect2
- MECR | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55284860; called by muse, mutect2, varscan2
- MET | c.4132G>A p.E1378K | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); catalogued as COSV59256037, COSV59259134, COSV59269575; called by muse, mutect2, varscan2
- METAP1D | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as COSV59929425; called by muse, mutect2, varscan2
- MKI67 | c.3696G>C p.Q1232H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV64073530; called by muse, mutect2, varscan2
- MRFAP1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100307700, COSV100307713; called by muse, mutect2, varscan2
- MRPS35 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50011275; called by muse, mutect2, varscan2
- MSRA | c.421del p.H141Tfs*33 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV57800440, COSV57803097; called by mutect2, pindel, varscan2
- MUC4 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV62139127; called by muse, mutect2, varscan2
- MYBL2 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53828803; called by muse, mutect2, varscan2
- MYT1L | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201761335, COSV67714823; called by muse, mutect2, varscan2
- MYZAP | c.1297C>A p.L433I (on ENST00000267853 / NM_001018100.5; = p.L405I on NM_152451.7) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV51089195; called by muse, mutect2, varscan2
- NAT10 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV57662990; called by muse, mutect2, varscan2
- NBAS | c.6436G>A p.D2146N | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV55716877; called by muse, mutect2, varscan2
- NBEAL1 | c.5487G>C p.L1829F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71374023; called by muse, mutect2, varscan2
- NEMF | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1368652354, COSV53590163; called by muse, mutect2, varscan2
- NFATC1 | c.2621G>T p.R874L (on ENST00000427363 / NM_001278669.2; = p.R861L on NM_172387.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs375156883, COSV53697546; called by muse, mutect2, varscan2
- NFATC2IP | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV57910008, COSV57911297; called by muse, mutect2, varscan2
- NFATC4 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51599078; called by muse, mutect2, varscan2
- NR3C1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51541455; called by muse, mutect2, varscan2
- NUDCD2 | c.239-1G>C p.X80_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100243690, COSV57084415; called by muse, mutect2, varscan2
- NUDT9 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV56196309; called by muse, mutect2, varscan2
- NUP155 | c.2078G>T p.R693I (on ENST00000231498 / NM_153485.3; = p.R634I on NM_004298.4) | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV51528460; called by muse, mutect2, varscan2
- NUP210 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV54404529; called by muse, mutect2, varscan2
- OPN5 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV55244775, COSV55244988, COSV55246285; called by muse, mutect2, varscan2
- OR2T10 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100393561, COSV57896483; called by muse, mutect2
- OR2T34 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60900029; called by muse, mutect2, varscan2
- OR4D10 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV73259955, COSV73259996; called by muse, mutect2, varscan2
- OR4X1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186874, COSV60722516; called by muse, mutect2, varscan2
- OR51E2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV67807139; called by muse, mutect2, varscan2
- OR51S1 | c.468T>G p.I156M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV59057891; called by muse, mutect2, varscan2
- OR8B12 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.311); catalogued as COSV60911406; called by muse, mutect2, varscan2
- PANK4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.257); catalogued as rs745365426, COSV65866273; called by muse, mutect2, varscan2
- PCDHB3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1554272605, COSV50567269; called by muse, mutect2, varscan2
- PCDHGA7 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.639); catalogued as COSV53903729, COSV53920818; called by muse, mutect2, varscan2
- PCF11 | c.2728C>G p.Q910E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as COSV53529240; called by muse, mutect2, varscan2
- PDE3B | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV56381652; called by muse, mutect2, varscan2
- PHC2 | c.2389G>C p.E797Q (on ENST00000257118 / NM_198040.2; = p.E262Q on NM_004427.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV57103051; called by muse, mutect2, varscan2
- PHEX | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV65074628; called by muse, mutect2, varscan2
- PHLDB2 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV67309630; called by muse, mutect2, varscan2
- PHOX2B | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs587778606, COSV56929028; called by mutect2, varscan2
- PIEZO2 | c.6676G>A p.E2226K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53287721; called by muse, mutect2, varscan2
- PKD1L1 | c.2837-1G>C p.X946_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56961453; called by muse, mutect2, varscan2
- PKD2 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV52937467; called by muse, mutect2, varscan2
- PLAAT1 | c.577G>A p.E193K (on ENST00000650797; = p.E88K on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as COSV53230653; called by muse, mutect2, varscan2
- PLCL1 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1186222557, COSV101407280, COSV70824270; called by muse, mutect2, varscan2
- PLEKHS1 | c.466C>G p.L156V (on ENST00000369310 / NM_182601.1; = p.L162V on NM_024889.5) | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); catalogued as COSV63054530; called by muse, mutect2, varscan2
- PLTP | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62464288; called by muse, mutect2, varscan2
- POU3F1 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100884734; called by muse, mutect2
- PPEF2 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54421315; called by muse, varscan2
- PPIL2 | c.33-1G>A p.X11_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58605609; called by muse, mutect2, varscan2
- PPM1K | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55795479; called by muse, mutect2, varscan2
- PRAMEF12 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV63214959; called by muse, mutect2, varscan2
- PRDM13 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as COSV65029241; called by muse, mutect2, varscan2
- PRKG1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV64824978; called by muse, varscan2
- PRSS16 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57914915, COSV57917237; called by muse, mutect2
- RB1 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 193/280 reads (69%) | catalogued as COSV57301410, COSV57303024; called by muse, mutect2, varscan2
- RBP4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101012310; called by muse, mutect2
- REC8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs947839500, COSV61015769; called by muse, mutect2
- REC8 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61015779; called by muse, mutect2, varscan2
- RIPOR2 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV52419004; called by muse, mutect2, varscan2
- RNF17 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55037020; called by muse, mutect2
- RNF214 | c.1269G>T p.R423S | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV56118161; called by muse, mutect2, varscan2
- RNH1 | c.612C>G p.L204= | Splice Region (SNP) | VAF 11/39 reads (28%) | catalogued as COSV62250680; called by muse, mutect2, varscan2
- RNMT | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs760567801, COSV51084473; called by muse, varscan2
- RNMT | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51084503; called by muse, varscan2
- ROS1 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV63853396; called by muse, mutect2, varscan2
- RREB1 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1285855648, COSV58555685; called by muse, mutect2, varscan2
- RRP15 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV65117618; called by muse, mutect2, varscan2
- RTEL1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58892119; called by muse, mutect2, varscan2
- RTTN | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55343040; called by muse, mutect2, varscan2
- SAMD11 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs770756813, COSV100498223; called by muse, varscan2
- SF3B3 | c.3546C>G p.F1182L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs768531551, COSV56786334; called by muse, mutect2, varscan2
- SH3TC1 | c.3693G>C p.E1231D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55282844; called by muse, mutect2
- SLC20A1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55610675; called by muse, mutect2, varscan2
- SLC30A6 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV50872171; called by muse, mutect2, varscan2
- SLC35G2 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 134/289 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV67588076; called by muse, mutect2, varscan2
- SLCO5A1 | c.1149A>T p.K383N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV52656562; called by muse, mutect2, varscan2
- SMCHD1 | c.4520C>T p.S1507L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs528136845, COSV55253936; called by muse, mutect2, varscan2
- SNCAIP | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV54402621; called by muse, mutect2, varscan2
- SPA17 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs763651030, COSV57032135, COSV99907299; called by muse, mutect2, varscan2
- ST7 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55382608; called by muse, mutect2, varscan2
- ST8SIA4 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | PolyPhen benign (0.099); catalogued as COSV51508334; called by muse, mutect2, varscan2
- SYNE1 | c.22987G>T p.E7663* (on ENST00000367255 / NM_182961.4; = p.E7592* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | catalogued as COSV99583603; called by muse, mutect2, varscan2
- SYT4 | c.1030C>G p.H344D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54899337, COSV54899899; called by muse, mutect2, varscan2
- TAGAP | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1463963351, COSV57851004; called by muse, mutect2, varscan2
- TAPBP | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1339997006, COSV69667131; called by muse, mutect2, varscan2
- TCFL5 | c.1173G>C p.Q391H | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV53895945, COSV99415839; called by muse, mutect2, varscan2
- TCHH | c.1323G>C p.E441D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | PolyPhen benign (0.043); catalogued as COSV100915599; called by muse, varscan2
- TEX264 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV58133903; called by muse, mutect2, varscan2
- TGFB1I1 | c.802G>C p.E268Q (on ENST00000394863 / NM_001042454.3; = p.E251Q on NM_015927.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62357527, COSV62357762; called by muse, mutect2, varscan2
- TGIF2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV65836357; called by muse, mutect2, varscan2
- THBS1 | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99528556; called by muse, mutect2
- TMPRSS6 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381747373, COSV60976599; called by muse, mutect2, varscan2
- TNFRSF10D | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100441942; called by muse, mutect2
- TOP3A | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58176287; called by muse, mutect2, varscan2
- TRADD | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV61460014; called by muse, mutect2, varscan2
- TRAPPC12 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100161071; called by muse, mutect2
- TRIP10 | c.140+1G>A p.X47_splice | Splice Site (SNP) | VAF 13/26 reads (50%) | catalogued as COSV51184402; called by muse, mutect2, varscan2
- TRO | c.1854G>A p.M618I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV99437505; called by muse, mutect2
- TSPAN15 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64782445; called by muse, mutect2, varscan2
- TSPAN8 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV99922767; called by muse, mutect2
- TTN | c.80785T>C p.C26929R (on ENST00000591111; = p.C19505R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | PolyPhen possibly damaging (0.595); catalogued as rs753342822, COSV59962840; called by muse, mutect2, varscan2
- TUBB4A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.514); catalogued as rs1014141628, COSV51152913; called by muse, mutect2, varscan2
- TUBG1 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.135); catalogued as COSV52220807; called by muse, mutect2, varscan2
- TUBGCP6 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50539843; called by muse, mutect2, varscan2
- UGGT1 | c.1995C>A p.F665L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV52132403, COSV52133834; called by muse, mutect2, varscan2
- UGT3A2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929380; called by muse, mutect2, varscan2
- USH1G | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs727504890, COSV58881202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VCAN | c.5836C>G p.H1946D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV54101611; called by muse, mutect2, varscan2
- VIRMA | c.3209C>G p.T1070S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV52583450; called by muse, mutect2, varscan2
- VIT | c.1766C>G p.S589C (on ENST00000389975 / NM_001177969.1; = p.S604C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64895896; called by muse, mutect2, varscan2
- WDR11 | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV54786722; called by muse, mutect2, varscan2
- WFDC12 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.825); catalogued as COSV65660922, COSV65661187; called by muse, mutect2, varscan2
- YY1 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV51761577; called by muse, mutect2, varscan2
- ZBTB11 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs202019961, COSV57244537; called by muse, mutect2, varscan2
- ZFP57 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 18/374 reads (5%) | catalogued as COSV100971998; called by muse, mutect2
- ZFYVE9 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV55092172; called by muse, mutect2, varscan2
- ZIM3 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV54141282; called by muse, mutect2, varscan2
- ZNF217 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs373838524; called by muse, mutect2, varscan2
- ZNF233 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61933446; called by muse, mutect2, varscan2
- ZNF236 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99471475; called by muse, mutect2, varscan2
- ZNF280C | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63968727; called by muse, mutect2, varscan2
- ZNF318 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58931375; called by muse, mutect2, varscan2
- ZNF493 | c.1289C>A p.S430* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100828992; called by muse, mutect2, varscan2
- ZNF555 | c.1523A>G p.Y508C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs566249058, COSV62072978; called by muse, mutect2, varscan2
- ZNF574 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV55902495; called by muse, mutect2, varscan2
- ZNF638 | c.1490G>A p.R497K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52484434; called by muse, mutect2, varscan2
- ZNF75D | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV100883708; called by muse, mutect2, varscan2
- ZNF780B | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.265); catalogued as COSV55462944; called by muse, mutect2
- ZSCAN20 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100792772; called by muse, mutect2, varscan2
- CDKN1A | c.110dup p.M38Nfs*10 | Frame Shift Ins (INS) | VAF 32/59 reads (54%) | called by mutect2, pindel, varscan2
- OR6V1 | c.843del p.L283Sfs*24 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- TPTE | c.690C>A p.Y230* (on ENST00000618007 / NM_199261.4; = p.Y212* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- ABCA13 | c.11574C>T p.V3858= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV71285114; called by muse, mutect2, varscan2
- ABCC9 | c.3378G>A p.G1126= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV53966468; called by muse, mutect2, varscan2
- ACOX1 | c.306C>T p.L102= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV53132229; called by muse, mutect2, varscan2
- ADGRB3 | c.3006C>T p.T1002= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV53239555; called by muse, mutect2, varscan2
- ALDH6A1 | c.1170G>A p.V390= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV63246071; called by muse, mutect2, varscan2
- AMMECR1L | c.414C>G p.L138= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1245449828, COSV55760273; called by muse, mutect2
- ANK2 | c.6030C>G p.L2010= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV52153288; called by muse, mutect2, varscan2
- APOM | c.333C>G p.L111= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as COSV99277805; called by muse, mutect2
- ARHGAP33 | c.1353G>A p.A451= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs201822304; called by muse, varscan2
- ARL14 | c.447G>T p.R149= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1314726746, COSV57899675; called by muse, mutect2, varscan2
- BLOC1S5 | c.102C>A p.L34= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99789607; called by muse, mutect2
- BTN1A1 | c.819C>T p.N273= | Silent (SNP) | VAF 115/243 reads (47%) | catalogued as rs370535758; called by muse, mutect2, varscan2
- CAPN12 | c.1698C>G p.L566= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV53144622; called by muse, mutect2
- CAPS | c.486C>T p.F162= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV50380674; called by muse, mutect2, varscan2
- CAVIN4 | c.357C>G p.V119= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV56866893; called by muse, mutect2, varscan2
- CCDC172 | c.753G>A p.Q251= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV60937229; called by muse, mutect2, varscan2
- CDC42EP3 | c.255C>T p.F85= | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as COSV54873794; called by muse, mutect2, varscan2
- CDSN | c.1440C>T p.S480= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1382345000, COSV52537639; called by muse, mutect2, varscan2
- CHRNA4 | c.1806C>T p.F602= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1359507082, COSV64718916; called by muse, mutect2, varscan2
- CHST3 | c.411C>T p.L137= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100910541; called by muse, mutect2, varscan2
- CPNE4 | c.1443G>A p.Q481= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV70192521; called by muse, mutect2, varscan2
- CPSF6 | c.1569G>A p.E523= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV57013445; called by muse, mutect2, varscan2
- CXXC4 | c.909G>A p.K303= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV67296123; called by muse, mutect2, varscan2
- DDX60L | c.549C>T p.L183= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99488713; called by muse, mutect2
- DELE1 | c.717C>G p.L239= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV52004371; called by muse, mutect2, varscan2
- DPH1 | c.210G>A p.K70= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV53984077; called by muse, mutect2, varscan2
- DSP | c.1114C>T p.L372= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV65792061; called by muse, mutect2, varscan2
- DYNC1H1 | c.7284G>A p.T2428= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs762065704, COSV64135480; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYTN | c.315C>T p.L105= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1299333100, COSV101124000; called by muse, mutect2, varscan2
- ECT2L | c.1437C>T p.F479= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1407844713, COSV62883646; called by muse, mutect2, varscan2
- EPRS1 | c.4458C>T p.L1486= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs1192043276, COSV65098115; called by muse, mutect2, varscan2
- EXPH5 | c.2181C>G p.P727= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV56200371; called by muse, mutect2, varscan2
- GOPC | c.219G>A p.L73= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV50001326; called by muse, mutect2, varscan2
- GREB1 | c.2793C>T p.I931= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV52183760; called by muse, mutect2, varscan2
- GTF2E1 | c.381C>T p.F127= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV52203821; called by muse, mutect2, varscan2
- H2BC15 | c.36G>A p.K12= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV57585283, COSV57586124; called by muse, varscan2
- HOXB2 | c.120G>A p.S40= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV57486294, COSV57488131; called by muse, mutect2, varscan2
- HSPA4L | c.69C>T p.I23= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56544574; called by muse, mutect2, varscan2
- IPO5 | c.1137G>A p.L379= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs749524307, COSV55153191; called by muse, mutect2, varscan2
- JADE2 | c.1215C>T p.Y405= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs751180082, COSV50913145; called by muse, mutect2, varscan2
- KCTD7 | c.606G>A p.V202= (on ENST00000275532; = p.E216K on NM_153033.5) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV51876558; called by muse, mutect2, varscan2
- KDELR3 | c.483C>T p.L161= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1335037338, COSV53247080; called by muse, mutect2, varscan2
- KIAA1217 | c.4914G>C p.V1638= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV56814759, COSV56822478; called by muse, mutect2, varscan2
- KNDC1 | c.4813C>T p.L1605= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100465205, COSV58834018; called by muse, mutect2, varscan2
- KRT26 | c.1326G>A p.L442= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as COSV59413563; called by muse, mutect2
- KRT8 | c.375C>T p.L125= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53176370, COSV99509828; called by muse, varscan2
- KRTAP10-6 | c.117G>A p.E39= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100555886; called by muse, varscan2
- LEO1 | c.1317G>C p.R439= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV55175237; called by muse, mutect2, varscan2
- LGALS4 | c.441C>T p.I147= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2
- LIMK2 | c.1674C>A p.L558= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV59181908, COSV59183074, COSV59184310; called by muse, mutect2, varscan2
- LYPD1 | c.165G>A p.Q55= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV58436211; called by muse, mutect2, varscan2
- MACF1 | c.19680G>C p.L6560= (on ENST00000372915; = p.L4605= on NM_012090.5) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV57113973; called by muse, mutect2, varscan2
- MAL | c.291C>G p.L97= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV59431068; called by muse, mutect2, varscan2
- MAP2K6 | c.687C>T p.L229= | Silent (SNP) | VAF 68/83 reads (82%) | catalogued as COSV100765063, COSV63005007; called by muse, mutect2, varscan2
- MCHR2 | c.882C>G p.L294= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV56001260; called by muse, mutect2, varscan2
- MMP9 | c.1641G>A p.G547= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV63433686, COSV63433910; called by muse, mutect2
- MTMR4 | c.873G>A p.L291= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100051545; called by muse, mutect2
- MUC16 | c.16653C>G p.L5551= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV67455698, COSV67494865; called by muse, mutect2, varscan2
- MYH6 | c.2583C>T p.I861= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV62449011; called by muse, mutect2
- NCLN | c.504C>T p.S168= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as rs145932625; called by muse, mutect2, varscan2
- NEK9 | c.1749C>G p.P583= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99464621; called by muse, mutect2
- NEU1 | c.1182G>A p.E394= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as COSV57666572; called by muse, mutect2, varscan2
- NLRC4 | c.939G>C p.L313= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV61592004; called by muse, mutect2, varscan2
- OR51E1 | c.867C>T p.L289= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV101211561, COSV67809579; called by muse, mutect2, varscan2
- OR52E6 | c.708C>G p.L236= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV61431647; called by muse, mutect2, varscan2
- OR56A1 | c.234C>T p.L78= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1280250650, COSV57362173; called by muse, mutect2, varscan2
- OSBPL6 | c.1293C>G p.L431= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV51914074; called by muse, mutect2, varscan2
- PGBD5 | c.738G>A p.L246= (on ENST00000525115; = p.L315= on NM_001258311.2) | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs570318016, COSV100358968; called by muse, varscan2
- PLXNA3 | c.2691G>A p.E897= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV63753594; called by muse, mutect2, varscan2
- PLXNA4 | c.5424G>A p.K1808= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100327691, COSV58114922; called by muse, mutect2, varscan2
- POLR2B | c.2733C>G p.L911= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV58899516; called by muse, mutect2, varscan2
- PRG4 | c.1569A>G p.A523= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV63355179; called by muse, mutect2, varscan2
- PTPRO | c.3594G>A p.K1198= (on ENST00000281171 / NM_030667.3; = p.K1170= on NM_002848.4) | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV55506269; called by muse, mutect2
- PYGB | c.1578C>T p.V526= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs1458984805, COSV53817047; called by muse, mutect2, varscan2
- SLAMF9 | c.63C>G p.L21= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV63636427; called by muse, mutect2, varscan2
- SLC7A7 | c.1383C>T p.I461= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV53536726; called by muse, mutect2
- SMARCC2 | c.1998C>T p.F666= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1364554724, COSV57215809; called by muse, mutect2, varscan2
- SOS2 | c.135C>T p.L45= | Silent (SNP) | VAF 35/248 reads (14%) | catalogued as COSV53565660; called by muse, mutect2, varscan2
- TARBP2 | c.1100G>A p.*367= (on ENST00000266987 / NM_134323.2; = p.*346= on NM_004178.4) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99908671; called by muse, mutect2, varscan2
- TEP1 | c.2142G>A p.T714= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs34817105, COSV99402188; called by muse, mutect2
- TIE1 | c.297C>T p.L99= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs780427692, COSV100992241; called by muse, mutect2, varscan2
- UNC5C | c.2697G>A p.Q899= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV71658854; called by muse, mutect2, varscan2
- VIPR2 | c.1134G>A p.L378= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV51104515; called by muse, mutect2, varscan2
- WDR11 | c.2733G>A p.Q911= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV54786733, COSV99676568; called by muse, mutect2, varscan2
- WNT7B | c.684G>A p.L228= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV59749038; called by muse, mutect2, varscan2
- WT1 | c.1278C>G p.L426= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV60069309; called by muse, mutect2, varscan2
- ZNF426 | c.951C>T p.F317= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV53468676; called by muse, mutect2, varscan2
- ABHD3 | c.555+347C>A | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100004652, COSV56677809; called by muse, mutect2, varscan2
- ANKRD53 | c.904-435G>C | Intron (SNP) | VAF 10/84 reads (12%) | catalogued as COSV55536814; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12606G>A | Intron (SNP) | VAF 24/137 reads (18%) | catalogued as rs375726733; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445771 G>C | 3'Flank (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-18298G>C | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99960400; called by muse, mutect2
- INSIG1 | c.*31G>A | 3'UTR (SNP) | VAF 13/69 reads (19%) | catalogued as COSV60920087; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2765G>A | RNA (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- SLC22A17 | n.827C>T | RNA (SNP) | VAF 18/58 reads (31%) | catalogued as COSV52835231; called by muse, mutect2, varscan2
